Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANF, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANF-01A (Primary Tumor).

[page 1 of 2]
Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testis

Clinical History
Right testicular mass

ICD O-3
Seminoma NOS 9061/3
Site R Testis NOS C62.9
Q103/31/14

Gross Description

Received in formalin and labeled Right testis and consists of a testis (8 x 6.5 x 6 cm.) which is attached to a segment of spermatic cord (9 cm. in length, 1.3 cm. in diameter). The entire specimen weighs 130 grams. The epididymis measures 1.9 x 0.5 x 0.2 cm. The testis is bivalved opened and shows that the testis is entirely replaced by a multinodular, soft, light tan tumor, with a few nodules on the superior aspect being softened, necrotic, caseous and light yellow. Upon serial sectioning the spermatic cord the tumor does not appear to grossly involve the spermatic cord. Upon sectioning through the tumor, the cut surface is solid, nodular, soft, and with areas of homogeneous, bright yellow nodules and areas of necrosis. The tunica albuginea appears grossly intact. Representative sections are submitted.

- 1 spermatic cord margin and epididymis
- 2-6 representative sections through tumor
- 7 section through spermatic cord and tumor

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

[page 2 of 2]
SURGICAL PATHOL

(Continued)

Acct#:

Final Pathologic Diagnosis

Right testis: Seminoma, classic type, 8 cm in greatest dimension.

-Tumor is limited to testis and shows extensive area of necrosis. No direct extension beyond tunica albuginea.

-Epididymis is not involved.

-Spermatic cord is negative.

-Lymphovascular invasion is not identified.

Pathologic Stage: T1NXMX (Stage IA)

Attending Pathologist:

***Electronically Signed Out By

.***

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Source: NCI Genomic Data Commons file 18296530-fa3e-4edc-8068-c75267ddcde4 (TCGA-XE-AANF-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).